Gene-level copy-number profile of tumor specimen TCGA-CR-7367-01A from TCGA case TCGA-CR-7367, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 52.3 years (19,116 days).
Specimen TCGA-CR-7367-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.bdde97ac-7788-49b5-8e1c-0f5934c7ceac.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-7367-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6a32a806-fd6c-418a-a916-704e2be4f5ed

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 3,190; copy number 2: 5,877; copy number 3: 20,673; copy number 4: 13,450; copy number 5: 10,952; copy number 6: 4,614; copy number 8: 449; copy number 9: 289; copy number 10: 48; copy number 11: 16; copy number 12: 151; copy number 14: 68; copy number 16: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7367-01A-11D-2010-01): tumor purity 0.34, ploidy 3.38, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,170,274–88,186,636, 1 gene: THNSL2.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,050 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:184,902,111–201,229,406, 223 genes, copy number 9–14 (within-gene range 2–14) (broad region; genes not listed).
- chr2:201,288,271–201,780,956, 20 genes, copy number 10 (within-gene range 2–10): FLACC1, TRAK2, STRADB, SCYL2P1, Y_RNA, C2CD6, MTCO2P16, MTATP6P16, MTCO3P16, MTND3P16, MTND4LP16, MTND4P29, MTND5P31, TMEM237, ENO1P4, AC007279.1, MPP4, RNU6-651P, ALS2, RPS2P16.
- chr5:55,233,934–55,995,022, 18 genes, copy number 9 (within-gene range 5–9): AC026704.1, DHX29, MTREX, AC020728.1, PLPP1, AC010480.1, MIR5687, RNF138P1, AK4P2, SLC38A9, DDX4, AC016632.1, RNA5SP183, HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2.
- chr5:55,995,167–56,003,649, 2 genes, copy number 9: FLJ31104, AC016596.1.
- chr7:46,969,644–62,275,678, 234 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr8:111,093,263–143,430,732, 411 genes, copy number 8–16 (within-gene range 6–16) (broad region; genes not listed).
- chr12:115,957,905–116,277,693, 1 gene, copy number 9 (within-gene range 2–9): MED13L.
- chr12:116,082,570–119,877,320, 72 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr14:84,739,942–85,516,934, 7 genes, copy number 10 (within-gene range 6–10): RNU6-976P, AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911.
- chr14:88,551,597–89,025,807, 9 genes, copy number 10 (within-gene range 6–10): AL162171.1, ZC3H14, AL162171.3, EML5, AL121768.1, RNU4-92P, TTC8, Y_RNA, AL137785.1.
- chr14:89,794,669–90,816,479, 23 genes, copy number 9 (within-gene range 6–9): EFCAB11, RAB42P1, TDP1, KCNK13, GLRXP2, Y_RNA, PSMC1, NRDE2, AL161662.1, RPL21P11, AL512791.2, CALM1, AL512791.1, LINC02317, LINC00642, AL096869.3, TTC7B, AL096869.1, AL096869.2, AL139193.1, AL139193.2, AL122020.2, AL122020.1.
- chr14:94,146,128–94,593,118, 12 genes, copy number 10: PPP4R4, SERPINA10, SERPINA6, SERPINA2, SERPINA1, AL132708.1, SERPINA11, SERPINA9, SERPINA12, AL132990.1, SERPINA4, SERPINA5.
- chr14:95,407,266–96,019,765, 18 genes, copy number 9: SYNE3, AL133467.1, SNHG10, SCARNA13, GLRX5, LINC02318, AL133467.2, AL133467.4, TCL6, AL133467.5, AL133467.3, AL133467.6, TCL1B, TCL1A, AL139020.1, AL133167.1, TUNAR, AL137190.1.

Autosomal genes at a single copy (total copy number 1): 812. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
